Somatic mutation profile of tumor specimen TCGA-29-1774-01A (aliquot TCGA-29-1774-01A-01W-0639-09) from TCGA case TCGA-29-1774, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 82.1 years (29,991 days).
Specimen TCGA-29-1774-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 81d73577-db1c-4c71-8412-71e6ecc346db.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-29-1774-10A (Blood Derived Normal), aliquot TCGA-29-1774-10A-01W-0639-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ea972fcd-7545-4e17-bba3-5fdefa8c18e7

The open-access MAF lists 53 somatic variants for this specimen: 41 protein-altering or splice-affecting, 10 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 10, Nonsense Mutation 4, Splice Region 2, RNA 1, In Frame Del 1, Frame Shift Ins 1, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.993G>C p.Q331H | Missense Mutation (SNP) | VAF 53/70 reads (76%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen benign (0.052); catalogued as CS125161, COSV52681350, COSV52690011, COSV52951377, COSV99391417; called by muse, mutect2, varscan2
- AASS | c.1927A>G p.N643D | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs746833955, COSV62789633; called by muse, mutect2, varscan2
- ADAM2 | c.1904G>T p.C635F | Missense Mutation (SNP) | VAF 9/154 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99697003; called by muse, mutect2
- ADAT1 | c.107C>T p.A36V | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777652272, COSV57186153; called by muse, mutect2, varscan2
- AMBRA1 | c.383G>T p.G128V | Missense Mutation (SNP) | VAF 42/69 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV54052262; called by muse, mutect2, varscan2
- AMY2B | c.1495G>T p.E499* | Nonsense Mutation (SNP) | VAF 280/787 reads (36%) | catalogued as COSV63714933; called by muse, mutect2, varscan2
- ARHGEF26 | c.595G>T p.E199* | Nonsense Mutation (SNP) | VAF 26/58 reads (45%) | catalogued as COSV62845461, COSV62851083; called by muse, mutect2, varscan2
- ATP6V0A2 | c.530C>T p.S177F | Missense Mutation (SNP) | VAF 50/167 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.246); catalogued as COSV57748695; called by muse, mutect2, varscan2
- BSCL2 | c.130G>T p.V44L | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.914); catalogued as COSV53654916; called by muse, mutect2, varscan2
- CA1 | c.268A>G p.R90G | Missense Mutation (SNP) | VAF 41/155 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56278197; called by muse, mutect2, varscan2
- CA5A | c.911G>A p.R304K | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as rs368142668; called by muse, mutect2, varscan2
- CBLL1 | c.531G>T p.L177F | Missense Mutation (SNP) | VAF 86/218 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV56028621; called by muse, mutect2, varscan2
- COL2A1 | c.127G>A p.D43N | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0.009); catalogued as COSV61529644; called by mutect2, varscan2
- DGKK | c.458C>A p.P153Q | Missense Mutation (SNP) | VAF 13/17 reads (76%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.32); catalogued as COSV65707061; called by muse, mutect2, varscan2
- DNAJC6 | c.2339C>A p.A780D | Missense Mutation (SNP) | VAF 57/143 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV54773148; called by muse, mutect2, varscan2
- DOCK2 | c.3523G>T p.V1175L | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.068); catalogued as COSV56972738, COSV99911083; called by muse, mutect2
- DROSHA | c.1631G>A p.R544H | Missense Mutation (SNP) | VAF 19/139 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs1032572786, COSV60774677; called by muse, mutect2, varscan2
- FAM169A | c.663G>A p.M221I | Missense Mutation (SNP) | VAF 198/492 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.315); catalogued as COSV100998323; called by muse, mutect2
- FAM219B | c.555C>A p.C185* | Nonsense Mutation (SNP) | VAF 6/57 reads (11%) | catalogued as COSV60396651; called by muse, mutect2, varscan2
- FNDC3A | c.3343C>T p.R1115C (on ENST00000492622 / NM_001079673.2; = p.R1059C on NM_014923.5) | Missense Mutation (SNP) | VAF 43/93 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.348); catalogued as COSV68132284; called by muse, mutect2, varscan2
- GIMAP6 | c.283G>C p.D95H | Missense Mutation (SNP) | VAF 70/191 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61033072; called by muse, mutect2, varscan2
- GRHL1 | c.979C>G p.R327G | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61405833, COSV61407502; called by muse, mutect2, varscan2
- HMGB3 | c.378G>T p.K126N | Missense Mutation (SNP) | VAF 36/51 reads (71%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV57485825; called by muse, mutect2, varscan2
- HROB | c.1379C>T p.T460M | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.091); catalogued as rs146791155; called by muse, mutect2, varscan2
- IGF2BP3 | c.285G>A p.E95= | Splice Region (SNP) | VAF 4/12 reads (33%) | catalogued as COSV51686021, COSV99325169; called by muse, mutect2
- INPP4B | c.641C>A p.A214D | Missense Mutation (SNP) | VAF 50/141 reads (35%) | SIFT tolerated (0.57); PolyPhen benign (0.289); catalogued as COSV53720035; called by muse, mutect2, varscan2
- POC1B-GALNT4 | c.556T>A p.Y186N | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV57964216; called by muse, mutect2, varscan2
- POMGNT1 | c.354G>A p.T118= | Splice Region (SNP) | VAF 3/28 reads (11%) | catalogued as rs1262087747, COSV100915463; called by muse, mutect2
- RNF128 | c.699G>T p.R233S (on ENST00000255499 / NM_194463.2; = p.R207S on NM_024539.3) | Missense Mutation (SNP) | VAF 15/300 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV55250794; called by muse, mutect2
- SIGLEC8 | c.164G>T p.G55V | Missense Mutation (SNP) | VAF 127/142 reads (89%) | SIFT tolerated (0.38); PolyPhen benign (0.139); catalogued as COSV58473164; called by muse, mutect2, varscan2
- SIRPA | c.1264C>T p.Q422* | Nonsense Mutation (SNP) | VAF 49/114 reads (43%) | catalogued as COSV61537890; called by muse, mutect2, varscan2
- TEKT3 | c.797G>A p.R266Q | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as rs771632343, COSV58627145; called by muse, mutect2, varscan2
- TOM1 | c.598G>A p.A200T | Missense Mutation (SNP) | VAF 28/40 reads (70%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs756741564, COSV65897819; called by muse, varscan2
- TRIM23 | c.1310G>T p.G437V | Missense Mutation (SNP) | VAF 48/121 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51550710; called by muse, mutect2, varscan2
- TRIM48 | c.466del p.L156Ffs*2 | Frame Shift Del (DEL) | VAF 20/47 reads (43%) | catalogued as COSV101338259; called by mutect2, pindel, varscan2
- TRPS1 | c.2411C>A p.P804Q (on ENST00000220888 / NM_001330599.2; = p.P817Q on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 58/169 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV55235159; called by muse, mutect2, varscan2
- TTN | c.53404G>T p.A17802S (on ENST00000591111; = p.A10378S on NM_003319.4) | Missense Mutation (SNP) | VAF 31/142 reads (22%) | PolyPhen benign (0.001); catalogued as COSV59988057; called by muse, mutect2, varscan2
- DSP | c.3922dup p.R1308Pfs*18 | Frame Shift Ins (INS) | VAF 83/183 reads (45%) | called by mutect2, pindel, varscan2
- ITPRIPL1 | c.902_910del p.S301_I303del (on ENST00000439118 / NM_001008949.3; = p.S309_I311del on NM_178495.6) | In Frame Del (DEL) | VAF 9/45 reads (20%) | called by mutect2, pindel, varscan2
- MAGEB6B | c.343C>A p.P115T | Missense Mutation (SNP) | VAF 6/97 reads (6%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.609); called by muse, mutect2
- RIN2 | c.2459G>T p.W820L (on ENST00000255006 / NM_001242581.1; = p.W771L on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 2/14 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- ACTL8 | c.111G>A p.P37= | Silent (SNP) | VAF 27/36 reads (75%) | catalogued as rs371845115, COSV64862461; called by muse, mutect2
- BMP1 | c.2073G>A p.V691= | Silent (SNP) | VAF 26/86 reads (30%) | catalogued as rs1246426723, COSV60478154; called by muse, mutect2, varscan2
- IMPG1 | c.183C>T p.F61= | Silent (SNP) | VAF 111/256 reads (43%) | catalogued as rs764226204, COSV64055878, COSV64057850; called by muse, mutect2, varscan2
- MAGEB6B | c.342T>A p.P114= | Silent (SNP) | VAF 6/96 reads (6%) | called by muse, mutect2
- NEK1 | c.3009A>G p.Q1003= | Silent (SNP) | VAF 56/152 reads (37%) | catalogued as rs760811823, COSV71455497; ClinVar: likely benign; called by muse, mutect2, varscan2
- PLCG2 | c.1623G>A p.T541= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as rs772797149, COSV100842695, COSV63866977; called by muse, mutect2, varscan2
- RBL1 | c.2847C>T p.Y949= | Silent (SNP) | VAF 14/76 reads (18%) | catalogued as rs1482096686, COSV60330857; called by muse, mutect2, varscan2
- SLC12A5 | c.3198C>T p.N1066= (on ENST00000454036 / NM_001134771.2; = p.N1043= on NM_020708.5) | Silent (SNP) | VAF 20/119 reads (17%) | catalogued as COSV51643822; called by muse, mutect2, varscan2
- SPTBN4 | c.7575G>C p.S2525= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as COSV52537368, COSV52539081; called by muse, mutect2, varscan2
- TPTE | c.738T>C p.I246= (on ENST00000618007 / NM_199261.4; = p.I228= on NM_199259.4) | Silent (SNP) | VAF 55/441 reads (12%) | called by muse, mutect2, varscan2
- CLCA3P | n.640C>T | RNA (SNP) | VAF 39/95 reads (41%) | catalogued as rs751635904; called by muse, mutect2, varscan2
- FBLN1 | c.1698-11484C>T | Intron (SNP) | VAF 17/25 reads (68%) | catalogued as rs763434568, COSV53044372; called by muse, mutect2, varscan2
